Somatic mutation profile of tumor specimen MBCProject_1321_T1_WES (aliquot MBCProject_1321_T1_WES_1) from CMI case MBCProject_1321, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.3 years (19,473 days).
Specimen MBCProject_1321_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4edfc8a-af27-4530-8732-16dcb71370c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1321_SALIVA (Saliva), aliquot MBCProject_1321_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88c39350-084a-47c2-b9c2-17c19e34c247

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Intron 3, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCG8 | c.63G>A p.S21= | Splice Region (SNP) | VAF 18/129 reads (14%) | catalogued as rs574659773; called by muse, mutect2, varscan2
- APOBR | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100112339; called by muse, mutect2, varscan2
- CTAGE1 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs767028750, COSV66943775; called by muse, mutect2, varscan2
- DENND2C | c.2458G>A p.E820K (on ENST00000393274 / NM_001256404.2; = p.E763K on NM_198459.4) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780932484, COSV67921285; called by muse, varscan2
- FAM71B | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV104407337; called by muse, varscan2
- GPNMB | c.1475C>T p.S492L (on ENST00000381990 / NM_001005340.2; = p.S480L on NM_002510.3) | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs148779588, COSV51701879; called by muse, mutect2, varscan2
- GZF1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV100582484; called by muse, mutect2, varscan2
- HLA-E | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100932006; called by muse, mutect2, varscan2
- LRRC49 | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.03); catalogued as COSV53013535; called by muse, mutect2, varscan2
- OR2J2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754259332, COSV101013291; called by muse, mutect2, varscan2
- PGPEP1L | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs201945671; called by muse, mutect2, varscan2
- PIK3C2G | c.1939G>A p.E647K (on ENST00000676171; = p.E606K on NM_004570.5) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.795); catalogued as COSV56803755, COSV56823957; called by muse, mutect2, varscan2
- RTL3 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as rs1175080621; called by muse, mutect2, varscan2
- SUSD3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs373769555; called by muse, mutect2
- ZBED1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs771134379, COSV58133119; called by muse, mutect2, varscan2
- CAPN7 | c.169dup p.I57Nfs*3 | Frame Shift Ins (INS) | VAF 18/146 reads (12%) | called by pindel, varscan2
- CEP170 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHD9 | c.3685G>C p.D1229H | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGA2 | c.1932T>A p.N644K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRTAC1 | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- DPY19L3 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- FAM170B | c.527A>G p.E176G | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- GPR150 | c.1171_1172insGT p.Q391Rfs*81 | Frame Shift Ins (INS) | VAF 22/158 reads (14%) | called by mutect2, pindel*, varscan2*
- HOXD8 | c.600_617del p.R201_R206del | In Frame Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- LRRC37A2 | c.4915-1G>C p.X1639_splice | Splice Site (SNP) | VAF 41/220 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.10618A>C p.T3540P | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MUC5B | c.5780C>A p.T1927N | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- NFASC | c.182T>C p.I61T (on ENST00000339876 / NM_001378329.1; = p.I55T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRARP | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SDCCAG8 | c.1439C>G p.A480G | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TCHH | c.4544G>C p.R1515T | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF570 | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGBD1 | c.768G>A p.P256= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as rs138163820; called by muse, mutect2, varscan2
- PKHD1L1 | c.7374A>G p.E2458= | Silent (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- QRICH1 | c.1308G>A p.Q436= | Silent (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- RAX2 | c.492G>A p.A164= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1014225698, COSV100349755; called by muse, mutect2
- SMTNL1 | c.1074C>T p.Y358= (on ENST00000399154; = p.Y395= on NM_001105565.2) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs543232675; called by muse, mutect2, varscan2
- TMC4 | c.1605C>T p.L535= (on ENST00000617472 / NM_001145303.3; = p.L529= on NM_144686.4) | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs1374976320; called by muse, mutect2, varscan2
- CENPW | c.126+20C>T | Intron (SNP) | VAF 38/176 reads (22%) | catalogued as rs375635063; called by muse, mutect2, varscan2
- PNCK | c.*246G>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | catalogued as COSV61744830; called by mutect2, varscan2
- PSMD6 | c.146-204C>G | Intron (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- USP40 | c.2380+56T>C | Intron (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
